Surgical pathology report (de-identified scan), TCGA case TCGA-23-2081, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2081-01A (Primary Tumor).

[page 1 of 4]
TCGA-23-2081

DIAGNOSIS:

3. UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES (HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY):
- Serous papillary Mullerian-derived adenocarcinoma involving:
- Right ovary (two foci 1-1.5 cm each, involving parenchyma and serosal surface)
- Left ovary (microscopic foci on serosal surface and in parenchyma)
- Uterine serosa
- Bilateral parametrial/paraovarian tissue
- Serosal organizing fibrinous exudate and mesothelial hyperplasia
- Weakly proliferative endometrium
- Mild chronic cervicitis with endocervical squamous metaplasia and nabothian cysts
- Bilateral ovaries with cystic follicles (and tumor as described above)
- Unremarkable bilateral fallopian tubes with no evidence of malignancy
- 1,2,4,5,7-11. OMENTUM, LESSER SAC TUMOR, CUL-DE-SAC TUMOR, RIGHT DIAPHRAGM TUMOR, LESSER OMENTUM SUPERCOLIC, GALLBLADDER TUMOR, MESENTERY TUMOR, CECAL TUMOR, LIVER TUMOR, AND SMALL BOWEL MESENTERY (EXCISION):
- Serous papillary Mullerian-derived adenocarcinoma
- Serosal organizing fibrinous exudate and mesothelial hyperplasia
6. APPENDIX (APPENDECTOMY):
- Appendix with rare clusters of malignant cells and a few psammoma bodies, entrapped within serosal fibrinous exudate
- No tumor invading appendiceal wall

NOTE: The adenocarcinoma shows features of a serous papillary Mullerian-derived adenocarcinoma showing macro and micro papillations and glandular structures. There is variable nuclear pleomorphism ranging from nuclear grade II to III. Numerous psammoma bodies are present and focal lymphatic invasion is identified. Rare microscopic foci exhibit clear cell features. It cannot be determined if the adenocarcinoma is of ovarian or primary peritoneal origin. Since there is relatively little ovarian involvement however, a peritoneal primary is favored.

HISTORY: Ovarian carcinoma

MICROSCOPIC:

[page 2 of 4]
See Diagnosis.

GROSS:

1. OMENTUM

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in the fresh state in the Operating Room for frozen section diagnosis and subsequently fixed in formalin is a 230 gms, 30.0 x 15.0 x 0.5 cm irregular portion of yellow lobulated hemorrhagic fibroadipose tissue, infiltrated with multiple foci of tan papillary tumoral masses ranging in size from 0.7 x 0.5 x 0.5 to 7.0 x 4.0 x 3.0 cm. Representative sections.

A: frozen-section remnants-1

B: omentum with tumor-2

2. LESSER SAC TUMOR

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is 1.5 x 1.0 x 0.7 cm portion of soft tan tissue. Entirely submitted.

C: 2

3. UTERUS, TUBES, OVARIES, CERVIX

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a uterus with attached bilateral adnexa which weighs 130 grams. The uterine corpus is symmetric, measuring 8.0 cm superior to inferior, 6.0 cm cornu to cornu, and 5.0 cm anterior to posterior. The serosa is tan-red and smooth with focal firm tan adhesions predominantly on the anterior aspect of the uterus. The cervix has a length of 3.2 cm and a diameter of 2.5 x 3.5 cm. There is a 1.3 cm slit-like patent os. The vaginal cuff ranges in thickness from 0.2 cm posteriorly to 0.4 cm anteriorly. There are no apparent gross abnormalities. The ectocervical mucosa is pink-white and smooth without obvious lesions. The transformation zone is distinct. The endocervical canal is 2.9 cm in length and is tan and rugose. The endometrial cavity is 3.5 cm in length, 2.3 cm in width, and is lined by a soft red-tan, smooth endometrium with a thickness of 0.2 cm. The endometrium is grossly unremarkable. The myometrium is 2.2 cm in maximum thickness. The myometrium is otherwise grossly unremarkable. The right ovary measures 2.5 x 2.0 x 1.0 cm and has two, 0.5 and 1.0 cm in greatest dimension, pink soft papillary masses on the external surface which penetrate into the ovarian parenchyma up to 0.7 cm. Ovary contains two focally hemorrhagic cysts, each 1.0 cm in average diameter. Uninvolved parenchyma contains corpora lutea. The right fallopian tube is 7.0 cm long and 0.7 cm in diameter, and is grossly unremarkable. The left ovary measures 2.5 x 1.5 x 1.0 cm and is unremarkable. The left fallopian tube is 7.0 cm long and 0.6 cm in diameter, and is grossly unremarkable. There is focal apparent gross tumor in the right parametrium, as well as in the peritoneal reflection. Portions of the ovaries were removed prior to receipt in pathology. Representative sections.

D: peritoneal reflection mass, uterine serosal adhesions - 2

E: right parametrial tissue-multiple

F: left parametrial tissue -3

G: anterior ecto / endocervix -1

H: posterior ecto/ endocervix -1

I: anterior endo /myometrium-1

J: posterior endo/ myometrium -1

K-L: right ovary with tumor-1

M: right ovary with cyst and tube-2

N: left ovary with tube-2

4. CUL-DE-SAC TUMOR

[page 3 of 4]
Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a 5.5 x 5.0 x 2.0 cm aggregate of granular yellow tan friable tissue grossly involved by the tumor. Representative sections.
O: 3

5. RIGHT DIAPHRAGM TUMOR

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are two soft tan irregular portions of tissue measuring 0.5 x 0.5 x 0.3 and 0.7 x 0.7 x 0.5 cm in greatest dimensions. Entirely submitted.
P: 3

6. APPENDIX

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a vermiform appendix, 5.0 cm long and 0.6 cm in maximum diameter, with attached fat up to 2.0 cm in width and 0.9 cm in thickness. The external surface is congested with fibrinous exudate identified. The wall varies in thickness up to 0.2 cm. and is firm and gray tan. No tumor is grossly seen. No fecalith is identified. Representative sections.
Q-R: 6 each
S: 2

7. LESSER OMENTUM SUPERCOLIC

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is 9.0 x 3.0 x 3.0 cm portion of red tan hemorrhagic fibroadipose tissue with gross focal involvement by tumor. Representative sections.
T: 1

8. GALLBLADDER TUMOR

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a friable tan 3.0 x 1.0 x 0.6 cm irregular portion of tissue with gross involvement by tumor. Representative sections.
U: 2

9. MESENTERY TUMOR

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are two soft tan irregular portions of tissue measuring 1.2 x 0.7 x 0.7 and 1.5 x 0.6 x 0.5 cm in greatest dimensions with gross tumor involvement. Representative sections.
V: 2

10. CECAL TUMOR

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are two soft tan irregular portions of tissue measuring 0.5 x 0.2 x 0.1 and 0.6 x 0.3 x 0.2 cm in greatest dimensions. Entirely submitted.
W: 2

11. LIVER TUMOR

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a 6.0 x 3.5 x 2.0 cm aggregate of tan friable tissue grossly involved by the tumor without recognizable liver tissue. Representative sections.
X: 2

12. SMALL BOWEL MESENTERY

[page 4 of 4]
Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are two soft tan irregular portions of tissue measuring 0.7 x 0.5 x 0.5 and 1.2 x 1.2 x 1.0 cm in greatest dimensions. Entirely submitted.
Y: 3

[REDACTED]

OPERATIVE CONSULT (FROZEN):

(#1) POORLY DIFFERENTIATED CARCINOMA COMPATIBLE WITH METASTATIC MULLERIAN-DERIVED CARCINOMA OR PRIMARY PERITONEAL CARCINOMA. PSAMMOMA BODIES FOCALLY PRESENT.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 4c86b6e4-b805-4427-8b38-e43d7a6f19b0 (TCGA-23-2081.05DC597F-052A-461E-A67C-27DAC0D10972.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).